MMRF case MMRF_1603 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c78ec315-bf9a-4c27-9a0a-adcd8b493bf8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.7 years (25,840 days); ISS stage: III; Days to last known disease status: 1,181 days (3.2 years); Days to last follow up: 1,181 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 280 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 280 days; Days to treatment end: 403 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 731 days (2.0 years); Days to treatment end: 819 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 731 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2377 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Beta 2 Microglobulin 11.2 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 231 µmol/L; Blood Urea Nitrogen 23.6 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 88: Hemoglobin 7.56 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 8.86 mmol/L.
- Day 270 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 57.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.18 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 7.28 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 9.4 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 371 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.33 mg/dL; Immunoglobulin G 5.63 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.36 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 6.49 mmol/L.
- Day 459 (ECOG 1): Hemoglobin 8.06 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 74 ×10⁹/L.
- Day 543 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 0 g/L; Immunoglobulin A 0 g/L; Immunoglobulin M 0 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 23 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 8.64 mmol/L.
- Day 630 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL; Immunoglobulin G 0 g/L; Immunoglobulin A 0 g/L; Immunoglobulin M 0 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 8.42 mmol/L.
- Day 714 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.21 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 8.53 mmol/L.
- Day 802 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 26.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 8.25 mmol/L.
- Day 918: Serum Free Immunoglobulin Light Chain, Kappa 68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 7.81 mmol/L.
- Day 1,001 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 4.77 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.29 µg/mL; Lactate Dehydrogenase 9.84 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 14.8 mmol/L.
- Day 1,110 (ECOG 1): Hemoglobin 8 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 8.6 ×10⁹/L; Platelets 116 ×10⁹/L.
- Day 1,181 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.545 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.147 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 10.5 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 11.7 mmol/L.

Other clinical attributes
- Day 1: Weight: 60 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1603_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1603_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
